Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A6GY, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A6GY-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

Final Results

Final

CASE NUMBER:

DIAGNOSIS: Adrenal gland, right (adrenalectomy): Pheochromocytoma.

CLINICAL INFORMATION: Brief Clinical History: yo female with history of pheochromocytoma, right adrenal mass now s/n right adrenalectomy Specimen Taken For Protocol:
Phone/Pager:

PROCEDURE: Pre-Operative Diagnosis: pheochromocytoma Post-Operative Diagnosis:
same Operative Findings: right adrenal mass

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT
2. RIB, Portion of right 12th

GROSS DESCRIPTION:

1. The specimen is received fresh labeled with the patient's name, medical record number and "right adrenal FS" and consists of a section of adrenal gland with a fairly circumscribed, encapsulated mass. Measurements are 5 x 4.5 x 3.5 cm and the specimen weighs 32 grams. Bisecting of the mass reveals a gray/pink largely hemorrhagic cut surface. Approximately 40% of the center of the mass is given to Research, the remainder to Surgical Pathology. The margin is inked in black. This procurement was performed by Dr. In Surgical Pathology, the specimen is received and is consistent with the above gross description. The specimen is further sectioned revealing an approximately 5 x 0.5 x 0.3 cm piece of grossly normal adrenal gland along one side of the specimen.
2. The specimen is received in formalin labeled with the patient's name, medical record number and "portion of right 12th rib". The specimen consists of three fragments of normal bone consistent with rib measuring in aggregate 10 x 0.75 x 0.6 cm in greatest dimensions. For gross description only.

Gross dictated by

INTRAOPERATIVE CONSULTATION:

1. Received fresh labeled with the patient's name, medical record number "right adrenal FS" is a specimen consisting of an adrenalectomy measuring 5 x 4.5 x 3.5 cm and weighing 32 grams. The specimen is bisected a touch prep is done. The remainder of the specimen is sent for procurement.

FS1 Diagnosis: Neuroendocrine tumor. The above diagnosis rendered by

Requested By:

Do not file in Medical Record

[page 2 of 2]
#

Requested By:

Do not file in Medical Record

Primary Malignancy History		
Concurrent/Synchronous Primary Noted		
Case i. (circle):		

hw 5/23/13

5/23/13

Source: NCI Genomic Data Commons file eb9ddbb9-ee2d-4114-a585-8cb18003fb84 (TCGA-QR-A6GY.EB45E32B-4108-4B47-B5AB-9646A68F0560.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).